Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A3B3, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A3B3-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

- A. Right pelvic lymph nodes; dissection:
- Four lymph nodes, no tumor present (0/4).
- B. Left pelvic lymph nodes; dissection:
- Four lymph nodes, no tumor present (0/4).
- C. Bladder; cystectomy:
- Papillary urothelial carcinoma, high grade, with squamous differentiation, transmurally invasive into perivesical adipose tissue.
- Multifocal urothelial carcinoma in-situ (flat urothelial carcinoma).
- No lymphovascular invasion present.
- Margins of resection (soft tissue, urethra, right and left ureter), no tumor present.
- Urinary bladder mucosa with ulceration, necrosis, inflammation and multinucleated giant cell reaction consistent with previous biopsy site.
- See pathologic parameters.
- D. Ovaries; oophorectomy:
- Ovaries with no significant pathology.
- Fallopian tubes with paratubal cysts.
- E. Right ureter segment; excision:
- Segment of ureter, no tumor present.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Papillary and flat urothelial carcinoma *ICD-O-3*
2. Grade of tumor: High grade
3. Depth of invasion: Perivesical adipose tissue
4. Tumor distribution: Multifocal, 3.8 x 2.2 cm *carcinoma, papillary urothelial*
8130/3
Path: Site: bladder, NOS C67.9
CQCF - bladder, trigone C67.0
hw
10/21/11

Left lateral wall

Right lateral wall

Trigone

Anterior wall
5. Ureteral margins: Negative
6. Distal urethral margin: Negative
7. Soft tissue margin or serosa: Negative
8. Lymph nodes: Eight lymph nodes, no tumor present (0/8)
9. pTNM: pT3N0Mx

Effective - this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xxx

[], M.D

Interpretation performed by the Attending Pathologist.

Electronically Signed Out by [] M.D

Clinical History:

The patient is a -year-old female with bladder cancer undergoing cystectomy

[page 2 of 3]
and ileal conduit.

Specimens Received:

- A: Right pelvic lymph nodes
- B: Left pelvic lymph nodes
- C: Bladder
- D: Ovaries
- E: Right ureter segment

Gross Description:

The specimens are received in five containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "right pelvic lymph node". Received fresh and placed in formalin are multiple soft tissue fragments aggregating to a total of 6.5 x 3 x 1 cm. Multiple lymph node candidates are dissected from the specimen ranging in size from 0.9 cm to 5.5 cm in longest dimension. The lymph node candidates are submitted as follows:

- A1: 2 possible lymph node candidates
- A2: One lymph node, serially sectioned
- A3-A4: One lymph node, serially sectioned

B. The second container is additionally identified as, "left pelvic lymph node". Received fresh and placed in formalin are multiple fibrofatty soft tissue fragments aggregating to a total of 6 x 4.5 x 1.5 cm. Multiple lymph node candidates are dissected from the specimen ranging in size from 0.9 cm to 2 cm and submitted as follows:

- B1: One lymph node candidate, bisected
- B2: One lymph node, entire
- B3: 2 possible lymph node candidates, entire
- B4: One lymph node, serially sectioned

C. The third container is additionally identified as, "bladder". Received fresh and place in formalin is a 167.1 g cystectomy specimen with overall measurements of 15 x 13.3 x 2.8 cm. The right ureteral stump measures 3.5 cm in length and 0.4 cm in diameter, and the left measures 1 cm in length and 0.4 cm in diameter. Both ureters demonstrate intact patent lumens. The serosal surface shows yellow lobulated fibroadipose tissue with focal cautery artifact. The urethral margin is inked black, and the bladder is inked blue on the right side and black on the left side. The specimen is opened anteriorly to reveal a 3.8 x 2.2 cm ulcerated, necrotic mass on the right lateral wall and trigone. In addition there is a 1.5 x 0.9 cm, superficial ulcerated lesion near the left trigone measuring 1.5 cm from the distal urethral margin. On cut section, the larger mass infiltrates into the muscularis propria to a depth of 1.1 cm and is 0.9 cm from the deep margin. The surrounding bladder mucosa is edematous, pink-tan with a uniform 1.0 cm wall thickness. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent.

Representative sections are submitted as follows:

- C1: Distal urethral margin
- C2: Right and left ureter resection margins (right inked blue)
- C3: Left lateral wall tumor, at maximum depth
- C4-C8: Additional sections of the ulcerative tumor
- C9-C10: Ulcerated lesion on the right side near the trigone
- C11: Uninvolved bladder mucosa bladder dome
- C12: Uninvolved bladder mucosa anterior wall
- C13: Uninvolved bladder mucosa, right lateral wall

D. The fourth container is additionally identified as, "ovaries". Received fresh and placed in formalin are unoriented, bilateral adnexal structures. One adnexa consists of a 4.1 cm long and 0.9 cm diameter fimbriated fallopian tube. The serosa is pink-red and glistening. The specimen is serially sectioned

[page 3 of 3]
revealing a pinpoint lumen and a 0.3 cm wall thickness. The attached white-tan, cribriform ovary measures 3 x 2.5 x 1 cm and is sectioned to reveal white and grossly unremarkable ovarian parenchyma. An occasional, yellowish firm nodule is palpable in the peritubal region. The other adnexa consist of a 3 cm long and 0.5 cm diameter fimbriated fallopian tube. The serosa is pink-red and glistening. The specimen is serially sectioned revealing a pinpoint lumen and a 0.3 cm wall thickness. The attached white-tan, cribriform ovary measures 2.5 x 2 x 1 cm and is sectioned to reveal fibrotic ovarian parenchyma. Representative sections are submitted as follows:

D1: First fallopian tube and ovary

D2: Yellowish nodules near the first adnexa

D3: Opposite fallopian tube and ovary

E. The fifth container is additionally identified as, "right ureter segment". Received fresh and placed in formalin is a segment of ureter measuring 0.9 cm in length and 0.5 cm in diameter. There is a suture designating the non-margin site. This side is inked blue. Opposite margin is inked green. The specimen is submitted entirely with the margin embedded en face in E1.

xx
[]

Source: NCI Genomic Data Commons file df602b43-18a3-46da-9c20-e6618f8cf04d (TCGA-FD-A3B3.F0E3A01E-2B43-4BE1-BAE5-85340943A422.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).